Somatic mutation profile of tumor specimen 0DY78R from CCDI case PBCSHW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Short bones of lower limb and associated joints; Age at diagnosis: 14.2 years (5,185 days).
Specimen 0DY78R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e207fab0-994e-400b-a61d-830094dfcf68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY77V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfcae78c-60c9-4f4c-9321-d98880ebca36

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESYT1 | c.2333A>G p.E778G | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2
- GARNL3 | c.1597C>A p.H533N | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHA8 | c.201G>A p.A67= | Silent (SNP) | VAF 103/221 reads (47%) | catalogued as rs369468179, COSV65339616; called by muse, mutect2, varscan2
- SEC31A | c.3261C>T p.A1087= (on ENST00000355196 / NM_001318120.1; = p.A1048= on NM_016211.4) | Silent (SNP) | VAF 100/245 reads (41%) | catalogued as rs917155167, COSV52346538; called by muse, mutect2, varscan2
